Somatic mutation profile of tumor specimen TARGET-10-PATZSL-09A (aliquot TARGET-10-PATZSL-09A-01D) from TARGET case TARGET-10-PATZSL, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 10.0 years (3,663 days).
Specimen TARGET-10-PATZSL-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 20d78830-5207-422f-bde4-1033b945b7df.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PATZSL-10A (Blood Derived Normal), aliquot TARGET-10-PATZSL-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/616e22a2-c55f-40e6-a02d-d6a5c6845189

The open-access MAF lists 22 somatic variants for this specimen: 16 protein-altering or splice-affecting, 3 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 15, Silent 3, Intron 3, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AHI1 | c.1484G>A p.R495H | Missense Mutation (SNP) | VAF 31/76 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs387907003, CM118186, COSV55626877; ClinVar: pathogenic; called by muse, mutect2, varscan2
- FBXW7 | c.1393C>T p.R465C (on ENST00000281708 / NM_001349798.2; = p.R385C on NM_018315.5) | Missense Mutation (SNP) | VAF 20/42 reads (48%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs867384286, COSV55891008, COSV55897912, COSV99654845; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ALLC | c.146G>T p.W49L | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52994199; called by muse, mutect2, varscan2
- ANKRD30A | c.3631C>A p.Q1211K (on ENST00000611781; = p.Q1155K on NM_052997.2) | Missense Mutation (SNP) | VAF 10/93 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.031); catalogued as COSV64609152; called by muse, mutect2, varscan2
- CDK5RAP2 | c.4273C>T p.R1425W | Missense Mutation (SNP) | VAF 25/52 reads (48%) | SIFT deleterious (0.01); PolyPhen benign (0.076); catalogued as rs200356726, COSV62573841; called by muse, mutect2, varscan2
- DDAH1 | c.100A>G p.K34E | Missense Mutation (SNP) | VAF 5/9 reads (56%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV52303023; called by muse, mutect2
- EIF4E1B | c.148C>T p.R50W | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as rs749386549, COSV53780036, COSV53780052; called by muse, mutect2, varscan2
- FAM178B | c.1901C>T p.T634M (on ENST00000490605 / NM_001122646.3; = p.T74M on NM_016490.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.942); catalogued as rs137921256; called by muse, mutect2
- GNAS | c.169G>A p.E57K | Missense Mutation (SNP) | VAF 63/127 reads (50%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.218); catalogued as rs1366694636, COSV58326324, COSV58333493; called by muse, mutect2, varscan2
- GPKOW | c.1363C>A p.Q455K | Missense Mutation (SNP) | VAF 37/81 reads (46%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as COSV50242531; called by muse, mutect2, varscan2
- HLA-B | c.415C>T p.Q139* | Nonsense Mutation (SNP) | VAF 16/27 reads (59%) | catalogued as COSV69521147; called by muse, mutect2, varscan2
- LUZP2 | c.856G>A p.D286N | Missense Mutation (SNP) | VAF 23/45 reads (51%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as COSV61202609; called by muse, mutect2, varscan2
- NOTCH1 | c.4754T>C p.L1585P | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV53025649, COSV53029975, COSV53033143; called by muse, varscan2
- RALGAPA1 | c.2293C>T p.R765C | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.928); catalogued as rs565490640, COSV51881604; called by muse, mutect2, varscan2
- SCRIB | c.854T>C p.I285T | Missense Mutation (SNP) | VAF 13/89 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.69); catalogued as COSV57585863; called by muse, mutect2, varscan2
- U2AF2 | c.445C>T p.R149W | Missense Mutation (SNP) | VAF 21/39 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58273502; called by muse, mutect2, varscan2
- CSMD2 | c.4698C>T p.N1566= | Silent (SNP) | VAF 7/44 reads (16%) | catalogued as rs377415018; called by muse, mutect2, varscan2
- LDOC1 | c.252C>T p.N84= | Silent (SNP) | VAF 34/74 reads (46%) | called by muse, mutect2, varscan2
- MMP15 | c.1245G>T p.L415= | Silent (SNP) | VAF 23/48 reads (48%) | called by muse, mutect2, varscan2
- ARHGEF18 | c.493+22C>T | Intron (SNP) | VAF 7/39 reads (18%) | catalogued as rs764799847; called by muse, mutect2, varscan2
- PTTG1IP | c.169-476G>C | Intron (SNP) | VAF 9/22 reads (41%) | called by muse, mutect2, varscan2
- SUGT1P3 | n.215-1371G>A | Intron (SNP) | VAF 21/57 reads (37%) | called by muse, mutect2, varscan2
